Surgical pathology report (de-identified scan), TCGA case TCGA-AY-A71X, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-A71X-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Colon, right, laparoscopic colectomy

Tumor Histologic Type: colorectal adenocarcinoma arising in conjunction with tubulovillous adenoma with high grade dysplasia

Histologic Grade: moderately differentiated

Tumor Location: cecal pouch

Depth of Invasion:

-Into but not through muscularis propria

Lymphovascular Invasion: not identified

Perineural Invasion: not identified

Margins:

Proximal margin: negative for malignancy; tumor is 5.2 cm from proximal margin (gross measurement)

Distal margin: negative for malignancy; tumor is 14.6 cm from the distal margin (gross measurement)

Mesenteric margin: negative for malignancy; tumor is 5.9 cm from the mesenteric margin (gross measurement)

Distance of carcinoma from closest margin (specify): 5.2 cm, proximal margin

Regional Lymph Nodes: 28 lymph nodes, negative for malignancy (0/28)

Additional Pathologic Findings:

- Tubulovillous adenoma separate from tumor, 2.7 cm in greatest dimension with focal high grade dysplasia
- Appendix with acute serositis

AJCC Pathologic TNM Stage: pT2 pN0

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

CEC 1408-3
Adenocarcinoma 1408
814013

path
Adenocarcinoma in
tubulovillous adenoma
8263/3
Site Cecum C18.0
9/11/13

[page 2 of 3]
Clinical History:

-year-old female with right colon cancer.

Gross Description:

Specimen A is labeled "right colon".

Specimen fixation: Formalin

Parts of bowel received: Terminal ileum (4.1 cm long x 3.3 cm in circumference), ascending colon (14.7 cm long x 5.7 cm in circumference), vermiform appendix (8.1 cm long x 0.6 cm in diameter) and attached mesentery (22.3 x 8.2 x 3.4 cm).

Measurement: Please see parts of bowel received.

Specimen integrity: Intact

Orientation: Inking: serosa overlying the cecal mass/blue, mesenteric margin/green

Tumor location: Cecal pouch

Gross appearance of tumor: Filling the cecal pouch is a tan/brown firm exophytic mass with well-defined rolled nodular borders. Also within the cecal pouch adjacent to the mass but not communicating with it is a soft tan/brown sessile polypoid polyp.

Tumor dimensions: The mass is 5.3 x 4.1 x 1.7 cm (protruding into the lumina) and the polyp is 2.7 x 2.3 x 1.7 cm.

Bowel circumference at tumor site: 7.7 cm

Circumferential growth: Mass and polyp occupy the entire cecal pouch and adjacent luminal circumference involved is approximately 60%.

Gross depth of invasion: The mass extends 0.9 cm through the muscularis propria, into the mesentery and grossly retracts the serosa, but does not extend through it. The polyp is confined to the mucosal surface.

Gross evidence of perforation through visceral peritoneum: No

Luminal obstruction: The cecal pouch portion of the lumen is completely obstructed, but the ascending colon lumen just distal to the mass is patent.

[page 3 of 3]
Gross distance of tumor from margins: The mass is 5.2 cm from the proximal mucosal margin, 14.6 cm from the distal mucosal margin, and 5.9 cm from the mesenteric margin. The polyp is 8.6 cm from the proximal margin, 14.9 cm from the distal mucosal margin, and 8.1 cm from the mesenteric margin

Other remarkable findings: The appendix is intact, curved and adherent within the mesentery. The serosa is purple/tan, smooth and glistening. The lumen is pinpoint with a tan mucosa. The appendix is uninvolved by mass and the mass is 1.8 cm from the appendical orifice.

Lymph nodes: Multiple lymph node candidates are identified ranging from 0.2 cm in greatest dimension up to 1.5 x 1.0 x 0.9 cm in greatest dimension.

Tissue submitted for special investigation: Tumor and normal are given to tumor procurement foundation.

Digital photograph taken: No

Block Summary:

A1 - Proximal mucosal margin, en face
A2-A3 - Distal mucosal margin, en face
A4 - Mesenteric margin, en face
A5 - Appendiceal orifice
A5-A9 - Sections of mass, A6 and A7 are deepest invasion
A10-A11 - Full thickness section of polyp, bisected
A12-A13 - Remainder of base of polyp as it inserts into the mucosa
A14 - Appendix
A15-A16 - Five lymph node candidates each
A17-A19 - Each contains one lymph node candidate, serially sectioned
A20 - One lymph node candidate, bisected
A21-A25 - Each contains one lymph node candidate, serially sectioned
A26-A27 - Each contains one lymph node candidate, bisected
A28 - One lymph node candidate, serially sectioned
A29 - Three lymph node candidates
A30 - One lymph node candidate, bisected
A31 - One lymph node candidate, serially sectioned
A32-A34 - One lymph node candidate, serially sectioned

Source: NCI Genomic Data Commons file 0b6dcf0e-3aad-4f3e-a070-70793bc02db0 (TCGA-AY-A71X.32360E38-C269-487F-806F-A3880DE9F3EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).